Somatic mutation profile of tumor specimen 0DPJT1 from CCDI case PBCDZY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,463 days).
Specimen 0DPJT1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c7980ad-1b8d-4941-8a5b-796f999cb0d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e161db5-6452-48cf-966a-a3b7c7364197

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 4 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Nonsense Mutation 4, Intron 4, Silent 4, 3'UTR 4, Frame Shift Ins 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 66/1204 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2
- ABCA7 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 34/762 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.079); catalogued as rs1301946758; called by muse, mutect2
- AC011462.1 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 135/663 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs373555514, COSV54198168; called by muse, mutect2, varscan2
- ADNP | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 63/787 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs780464991; called by muse, mutect2
- ATRNL1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 30/670 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs140372621; called by muse, mutect2
- BMS1 | c.2764G>A p.V922M | Missense Mutation (SNP) | VAF 41/615 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs547177767; called by muse, mutect2
- CCDC160 | c.540dup p.E181Rfs*20 | Frame Shift Ins (INS) | VAF 436/546 reads (80%) | catalogued as rs1436795808; called by mutect2, varscan2
- CREBBP | c.4375G>T p.E1459* | Nonsense Mutation (SNP) | VAF 52/822 reads (6%) | catalogued as rs943250389, COSV52126986; called by muse, mutect2
- CSMD2 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 261/751 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs867069952, COSV53961110; called by muse, mutect2, varscan2
- FILIP1 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 202/439 reads (46%) | catalogued as rs775141616, COSV52724965; called by muse, mutect2, varscan2
- GOLGA8S | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs571480938; called by muse, mutect2, varscan2
- HERC2 | c.6077C>T p.T2026M | Missense Mutation (SNP) | VAF 96/599 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs748164478; called by muse, mutect2, varscan2
- HPX | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 54/794 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764988248, COSV56418537; called by muse, mutect2
- LMO3 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 62/754 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs777979802; called by muse, mutect2
- MYO1F | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 105/827 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375221696; called by muse, mutect2, varscan2
- OR4K17 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 244/517 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV100210654; called by muse, mutect2, varscan2
- PRDM8 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 306/682 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.067); catalogued as rs1318258282, COSV60204438; called by muse, mutect2, varscan2
- SLC10A2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 66/990 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs147515410; called by muse, mutect2
- SLC12A2 | c.2917A>G p.I973V | Missense Mutation (SNP) | VAF 198/788 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs149957408; called by muse, mutect2, varscan2
- TRIM33 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 76/1140 reads (7%) | catalogued as COSV100635227, COSV61823103; called by muse, mutect2
- VCAN | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 46/1029 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV54098163, COSV99427388; called by muse, mutect2
- ZNF132 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 455/811 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs370065697; called by muse, mutect2, varscan2
- ZNF337 | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 330/784 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs770879147; called by muse, mutect2, varscan2
- ZNF836 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 277/1005 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.754); catalogued as rs367917078; called by muse, mutect2, varscan2
- ADGRG2 | c.2566G>A p.V856I (on ENST00000379869 / NM_001079858.3; = p.V853I on NM_005756.4) | Missense Mutation (SNP) | VAF 296/384 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ASB7 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 36/693 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- BAZ2A | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 369/951 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CASKIN1 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, mutect2
- CHIC1 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- COL9A1 | c.1750G>A p.V584I | Missense Mutation (SNP) | VAF 52/862 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2
- DBNDD2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 24/878 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- DOCK1 | c.3960dup p.Q1321Tfs*6 | Frame Shift Ins (INS) | VAF 278/540 reads (51%) | called by mutect2, varscan2
- HNRNPH1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 66/874 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.029); called by muse, mutect2
- KBTBD4 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5L2 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 352/1044 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2
- PCDH17 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 56/750 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- PCDHB1 | c.2055T>A p.N685K | Missense Mutation (SNP) | VAF 283/734 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- SH3BP4 | c.466dup p.Y156Lfs*3 | Frame Shift Ins (INS) | VAF 40/366 reads (11%) | called by mutect2, varscan2
- SON | c.3289T>C p.S1097P | Missense Mutation (SNP) | VAF 70/950 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- SSC4D | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2
- TSPY2 | c.608T>A p.L203* | Nonsense Mutation (SNP) | VAF 49/248 reads (20%) | called by mutect2, varscan2
- USP45 | c.1801C>A p.Q601K | Missense Mutation (SNP) | VAF 200/607 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF8 | c.345C>T p.A115= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as rs1438406745; called by muse, mutect2
- FAT4 | c.3183A>G p.E1061= | Silent (SNP) | VAF 183/880 reads (21%) | called by muse, mutect2, varscan2
- FAT4 | c.9396A>G p.S3132= | Silent (SNP) | VAF 106/1129 reads (9%) | called by muse, mutect2
- SLITRK5 | c.894G>A p.T298= | Silent (SNP) | VAF 46/682 reads (7%) | catalogued as rs1320711553; called by muse, mutect2
- ADGRD1 | c.187+2436C>T | Intron (SNP) | VAF 234/623 reads (38%) | catalogued as rs1467889815; called by muse, mutect2, varscan2
- DDB1 | c.62-64A>G | Intron (SNP) | VAF 53/134 reads (40%) | called by muse, mutect2, varscan2
- GZMA | c.*6C>T | 3'UTR (SNP) | VAF 176/598 reads (29%) | catalogued as rs766998499; called by muse, mutect2, varscan2
- HS1BP3 | c.623+74G>A | Intron (SNP) | VAF 8/111 reads (7%) | catalogued as rs948837794; called by muse, mutect2
- HTN1 | c.*33+53A>T | Intron (SNP) | VAF 33/262 reads (13%) | catalogued as rs1214585308, COSV55895344; called by mutect2, varscan2
- PSG9 | c.*17A>C | 3'UTR (SNP) | VAF 93/1485 reads (6%) | called by muse, mutect2
- REPIN1 | c.*80C>A | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- TARM1 | chr19:54081328 G>T | 5'Flank (SNP) | VAF 36/939 reads (4%) | catalogued as COSV71524926; called by muse, mutect2
- ZBTB24 | c.*39A>T | 3'UTR (SNP) | VAF 27/397 reads (7%) | called by muse, mutect2
